Gene-level copy-number profile of tumor specimen HCM-SANG-1090-C18-08A-01D-A80T-32 from HCMI case HCM-SANG-1090-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Colon, NOS; Tumor grade: G3.
Specimen HCM-SANG-1090-C18-08A-01D-A80T-32: Sample type: Post neo-adjuvant therapy; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 668575fb-5922-4b2c-9352-252490d7955b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1090-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/63c39f09-eb05-4ef6-9b2f-282ba7b2f805

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 201; copy number 2: 58,123; copy number 3: 70; copy number 4: 4.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 201. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
